Gene-level copy-number profile of tumor specimen TCGA-XM-A8RB-01A from TCGA case TCGA-XM-A8RB, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 68.7 years (25,080 days).
Specimen TCGA-XM-A8RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.6d52edd6-bbb2-4e12-975c-1bc0ea6dfdb7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XM-A8RB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e596382-4e7a-4c53-b50c-96dc3f1a78e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 9; copy number 2: 59,795.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XM-A8RB-01A-11D-A422-01): tumor purity 0.35, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,340,998, 14 genes: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
